Somatic mutation profile of tumor specimen MP2PRT-PAVXVV-TMP1-A (aliquot MP2PRT-PAVXVV-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVXVV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,778 days).
Specimen MP2PRT-PAVXVV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5b194a4-26fb-438e-97c1-bc642c997a6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXVV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXVV-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/975a71e2-2a0e-4ff8-9210-8cfe0ead1ec2

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Splice Region 2, Silent 2, In Frame Ins 1, 3'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF11 | c.921C>T p.S307= | Splice Region (SNP) | VAF 45/267 reads (17%) | catalogued as rs775770721; called by muse, mutect2, varscan2
- CCKBR | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 104/708 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV58102724; called by muse, mutect2, varscan2
- DISP3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 262/569 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs373256766; called by muse, mutect2, varscan2
- FAM13C | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53254285; called by muse, mutect2, varscan2
- HYAL4 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 111/432 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56137558; called by muse, mutect2, varscan2
- KDM4A | c.913C>T p.L305= | Splice Region (SNP) | VAF 121/275 reads (44%) | catalogued as rs1168492114; called by muse, mutect2, varscan2
- MRGPRF | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 70/575 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs1288243408; called by muse, mutect2, varscan2
- ATG2B | c.2588G>T p.R863I | Missense Mutation (SNP) | VAF 116/451 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHDC9 | c.603T>A p.H201Q | Missense Mutation (SNP) | VAF 75/475 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAPK8IP3 | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 108/601 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MEMO1 | c.169_170insGGG p.S57delinsWA | In Frame Ins (INS) | VAF 46/346 reads (13%) | called by mutect2, pindel*, varscan2
- NTF3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 105/532 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDIA2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 161/651 reads (25%) | called by muse, mutect2, varscan2
- POGLUT2 | c.1106A>T p.D369V | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRH | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- UNK | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 142/716 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF292 | c.3432_3436del p.N1144Kfs*5 | Frame Shift Del (DEL) | VAF 43/332 reads (13%) | called by mutect2, pindel, varscan2
- KNDC1 | c.1713G>A p.P571= | Silent (SNP) | VAF 60/681 reads (9%) | catalogued as rs1438725636; called by muse, mutect2
- VAT1L | c.591G>A p.V197= | Silent (SNP) | VAF 54/345 reads (16%) | catalogued as rs769675875, COSV100213314; called by muse, mutect2, varscan2
- PFN2 | c.*1253del | 3'UTR (DEL) | VAF 69/424 reads (16%) | called by mutect2, pindel, varscan2
